Somatic mutation profile of tumor specimen TCGA-D1-A0ZO-01A (aliquot TCGA-D1-A0ZO-01A-11D-A122-09) from TCGA case TCGA-D1-A0ZO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 75.2 years (27,482 days).
Specimen TCGA-D1-A0ZO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20d42cbd-aa53-4ca4-a00b-68b6e75300cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZO-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZO-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cda9c59-218b-41cf-b288-bf8fabec334f

The open-access MAF lists 732 somatic variants for this specimen: 564 protein-altering or splice-affecting, 162 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 360, Silent 162, Frame Shift Del 141, Frame Shift Ins 32, Nonsense Mutation 17, Splice Region 5, Intron 4, In Frame Del 4, Splice Site 3, 3'Flank 2, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs397514532, CM081154, COSV59874078; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2, varscan2
- CEP290 | c.3175del p.I1059* | Frame Shift Del (DEL) | VAF 96/304 reads (32%) | catalogued as rs62640570, CD073593; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GJB6 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28937872, CM002606, COSV53832929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LAMC2 | c.537del p.N180Tfs*67 | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | catalogued as rs745512079; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 132/562 reads (23%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 76/617 reads (12%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 78/240 reads (33%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PHYH | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894173, CM001297, COSV53816696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 91/278 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.900del p.I300Mfs*7 | Frame Shift Del (DEL) | VAF 252/476 reads (53%) | catalogued as rs797045904, CD115955, COSV64288931, COSV64289107; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 106/320 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- SCN2A | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 175/699 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121917748, CM012186; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TRIO | c.3657dup p.C1220Mfs*7 | Frame Shift Ins (INS) | VAF 66/274 reads (24%) | catalogued as rs1554068529; ClinVar: likely pathogenic; called by mutect2, varscan2
- TSC1 | c.2672del p.N891Tfs*40 | Frame Shift Del (DEL) | VAF 57/243 reads (23%) | catalogued as rs118203724, CD1111250, COSV53764493; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- ABCA8 | c.4318G>C p.E1440Q | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52197851, COSV52205913; called by muse, mutect2, varscan2
- ABCC1 | c.1484T>C p.M495T | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs1183784458, COSV60689047; called by muse, mutect2, varscan2
- ABCC12 | c.3517C>A p.P1173T | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV60915282; called by muse, mutect2, varscan2
- ABHD13 | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65535188; called by muse, mutect2
- ABTB2 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.116); catalogued as rs1052295344, COSV54391517; called by muse, mutect2, varscan2
- AC008676.3 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 6/118 reads (5%) | catalogued as rs1290797080, COSV56637203; called by muse, mutect2
- ACACB | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs527660684, COSV58131161; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 155/369 reads (42%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs371756878, COSV61702820; called by muse, mutect2, varscan2
- ADAD2 | c.592G>C p.A198P (on ENST00000315906 / NM_001145400.2; = p.A270P on NM_139174.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51894203; called by muse, mutect2, varscan2
- ADAMTS16 | c.2800G>A p.G934R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56996608; called by muse, mutect2, varscan2
- ADCY3 | c.2862A>T p.E954D | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53169505; called by muse, varscan2
- ADCYAP1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52486932; called by muse, mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | catalogued as rs1554870245; called by mutect2, varscan2
- AGAP2 | c.1933C>T p.R645C (on ENST00000547588 / NM_001122772.2; = p.R309C on NM_014770.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs537683521, COSV57729673; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs748399150; called by mutect2, varscan2
- AGT | c.1298A>C p.E433A | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV64184980; called by muse, mutect2, varscan2
- AKR7A2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.362); catalogued as COSV52516526; called by muse, mutect2, varscan2
- ALOX12B | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559401066, COSV59874094; called by muse, mutect2, varscan2
- ALS2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 149/655 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV51889189; called by muse, mutect2, varscan2
- ANKH | c.1129T>C p.F377L | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.931); catalogued as COSV52483106; called by muse, mutect2, varscan2
- ANKRD30A | c.3599C>A p.P1200H (on ENST00000611781; = p.P1144H on NM_052997.2) | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64614472; called by muse, mutect2, varscan2
- ANLN | c.2655G>A p.V885= | Splice Region (SNP) | VAF 125/353 reads (35%) | catalogued as rs748077424, COSV56077570; called by muse, mutect2, varscan2
- ANP32A | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 155/482 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV51189717; called by muse, mutect2, varscan2
- ANPEP | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756960671, COSV55592871; called by muse, mutect2, varscan2
- AP2A2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59961912; called by muse, mutect2, varscan2
- ARAP1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs559434428, COSV61992275; called by muse, mutect2, varscan2
- ARHGEF6 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51693203; called by muse, mutect2, varscan2
- ARID1A | c.5856del p.K1953Rfs*3 | Frame Shift Del (DEL) | VAF 41/142 reads (29%) | catalogued as COSV61381985; called by mutect2, pindel, varscan2
- ARID4A | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs773999866, COSV62165000; called by muse, mutect2, varscan2
- ARID4A | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as COSV62165007; called by muse, varscan2
- ARMC3 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53063953; called by muse, mutect2, varscan2
- ARSA | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM990172, COSV53350769; called by muse, mutect2, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | catalogued as rs773893016; called by mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 142/497 reads (29%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH1L | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.118); catalogued as rs753568698, COSV64209900; called by muse, mutect2, varscan2
- ATF7IP | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 13/469 reads (3%) | catalogued as COSV53773349; called by muse, mutect2
- ATP10A | c.4372C>T p.R1458W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs767096030, COSV63519484; called by muse, mutect2, varscan2
- AVPR1A | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV54547191; called by muse, mutect2, varscan2
- BICDL1 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 39/192 reads (20%) | catalogued as COSV57493948; called by muse, mutect2, varscan2
- BIRC6 | c.13509dup p.L4504Tfs*3 | Frame Shift Ins (INS) | VAF 28/74 reads (38%) | catalogued as rs749424971; called by mutect2, varscan2
- BLM | c.4018C>T p.P1340S | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV61925270, COSV61925281; called by muse, mutect2, varscan2
- BMS1 | c.2249T>C p.V750A | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs750831167, COSV65734518; called by muse, mutect2, varscan2
- BPHL | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761715848, COSV66744012; called by muse, mutect2, varscan2
- BRSK1 | c.618del p.K206Nfs*38 | Frame Shift Del (DEL) | VAF 69/268 reads (26%) | catalogued as COSV58666488; called by mutect2, pindel, varscan2
- C5orf38 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.858); catalogued as COSV57412143; called by muse, mutect2, varscan2
- CA1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 47/858 reads (5%) | catalogued as rs373804439, COSV56277599; called by muse, mutect2
- CAMK1D | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66614927; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 24/203 reads (12%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs745547658; called by mutect2, varscan2
- CANT1 | c.392del p.K131Rfs*4 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as COSV56605000; called by mutect2, pindel, varscan2
- CARD11 | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62755946; called by muse, mutect2, varscan2
- CARMIL1 | c.4033C>T p.R1345W | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs192384666, COSV61515283; called by muse, mutect2, varscan2
- CARMIL2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV58028802; called by muse, mutect2, varscan2
- CASP10 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs201601111, COSV53779333, COSV99629116; called by muse, mutect2, varscan2
- CBFA2T3 | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.377); catalogued as COSV51929479; called by muse, mutect2, varscan2
- CBL | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV50644912; called by muse, mutect2, varscan2
- CCAR1 | c.1295del p.N432Ifs*18 | Frame Shift Del (DEL) | VAF 118/399 reads (30%) | catalogued as rs951233372, COSV56273266; called by mutect2, pindel, varscan2
- CCDC61 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54429359; called by muse, mutect2
- CCDC87 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59579696; called by muse, mutect2, varscan2
- CCNA1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750419153, COSV55222625; called by muse, mutect2, varscan2
- CD276 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs751833994, COSV59203973; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 34/72 reads (47%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDCP1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV56106557; called by muse, mutect2
- CDK13 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51702730; called by muse, varscan2
- CEACAM5 | c.1802del p.P601Qfs*68 | Frame Shift Del (DEL) | VAF 68/249 reads (27%) | catalogued as rs782698410, COSV55750352; called by mutect2, pindel, varscan2
- CEP290 | c.2822T>C p.M941T | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV58353413; called by muse, mutect2, varscan2
- CERKL | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs371438602; called by muse, mutect2
- CFAP298 | c.375+2T>C p.X125_splice | Splice Site (SNP) | VAF 120/530 reads (23%) | catalogued as rs934312313, COSV51592700; called by muse, varscan2
- CFAP47 | c.4855A>G p.N1619D | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV57975030; called by muse, mutect2, varscan2
- CFHR2 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66381568; called by muse, mutect2, varscan2
- CFP | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs140986480, COSV55950688; called by muse, mutect2, varscan2
- CHAF1A | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1462007485, COSV56674104; called by muse, mutect2, varscan2
- CHD3 | c.3781G>A p.A1261T | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs752365619, COSV57874895; called by muse, mutect2, varscan2
- CIC | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs763135165, COSV50609999; called by muse, mutect2, varscan2
- CLCNKA | c.855dup p.V286Cfs*38 | Frame Shift Ins (INS) | VAF 81/288 reads (28%) | catalogued as rs753052635; called by mutect2, varscan2
- CLDN17 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 20/582 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV54523564; called by muse, mutect2
- CLOCK | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 212/728 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs754304462, COSV59403335; called by muse, mutect2, varscan2
- CNDP1 | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV62594377; called by muse, mutect2
- CNNM4 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV65661446; called by muse, varscan2
- CNNM4 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 151/326 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65661451; called by muse, varscan2
- CNTNAP2 | c.3418A>G p.S1140G | Missense Mutation (SNP) | VAF 167/589 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV62212219; called by muse, mutect2, varscan2
- COBLL1 | c.1547C>T p.P516L (on ENST00000392717; = p.P478L on NM_014900.5) | Missense Mutation (SNP) | VAF 237/554 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748344045, COSV52071086; called by muse, mutect2, varscan2
- COL4A6 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as rs767133960, COSV57871141; called by muse, mutect2, varscan2
- CRACDL | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV67409064; called by muse, mutect2
- CREBBP | c.6871C>A p.L2291M | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.142); catalogued as COSV52130316; called by muse, mutect2, varscan2
- CSMD3 | c.5836C>T p.R1946C (on ENST00000297405 / NM_001363185.1; = p.R1842C on NM_052900.3) | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377290204; called by muse, mutect2, varscan2
- CTNNBL1 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418919341, COSV63745707; called by muse, mutect2, varscan2
- CUEDC2 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV50041722, COSV99193899; called by muse, mutect2, varscan2
- CXXC1 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1320831401, COSV53275531; called by muse, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 112/320 reads (35%) | catalogued as rs745836350; called by mutect2, varscan2
- CYLC2 | c.581del p.K194Rfs*39 | Frame Shift Del (DEL) | VAF 92/463 reads (20%) | catalogued as rs766829527; called by mutect2, pindel, varscan2
- CYP4F11 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56128101, COSV99930731; called by muse, mutect2, varscan2
- CYTH2 | c.1168C>T p.R390W (on ENST00000427476; = p.R389W on NM_004228.7) | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs757256464, COSV57309859; called by muse, mutect2, varscan2
- DCLK1 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs1319516535, COSV55177734, COSV55194817; called by muse, mutect2, varscan2
- DDR1 | c.2198C>T p.A733V (on ENST00000324771; = p.A696V on NM_001954.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1219302418, COSV61322481; called by muse, mutect2, varscan2
- DEK | c.897del p.E300Kfs*13 | Frame Shift Del (DEL) | VAF 278/904 reads (31%) | catalogued as COSV99788881; called by mutect2, varscan2
- DEXI | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1440431138, COSV59328800; called by muse, mutect2, varscan2
- DHRS9 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59139519, COSV59140633; called by muse, mutect2
- DHTKD1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759869851, COSV53801975; called by muse, mutect2, varscan2
- DIAPH2 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs765131524, COSV61268916, COSV61278112, COSV61282411; called by muse, mutect2, varscan2
- DIMT1 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52234048; called by muse, mutect2
- DMD | c.9584G>C p.R3195P | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58892970, COSV58926071; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH3 | c.6217G>A p.V2073M | Missense Mutation (SNP) | VAF 261/646 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762157776, COSV54502748; called by muse, mutect2, varscan2
- DNAJC4 | c.381del p.N128Tfs*11 | Frame Shift Del (DEL) | VAF 33/141 reads (23%) | catalogued as rs1000579773; called by mutect2, pindel, varscan2
- DNER | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs748951182, COSV59170404; called by muse, mutect2, varscan2
- DOCK10 | c.5621T>C p.F1874S | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV51420070; called by muse, mutect2, varscan2
- DOP1B | c.636del p.G213Afs*16 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs1387444809; called by mutect2, pindel, varscan2
- DOP1B | c.5110A>G p.S1704G | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs144310448, COSV67694154; called by muse, mutect2, varscan2
- DTL | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs146481751; called by muse, mutect2, varscan2
- DYNC2I1 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV68105722; called by muse, mutect2
- E2F7 | c.314del p.K105Rfs*43 | Frame Shift Del (DEL) | VAF 82/356 reads (23%) | catalogued as COSV59740114; called by mutect2, pindel, varscan2
- ECE1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs199666282, COSV51664837; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 104/424 reads (25%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EFHC1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 121/366 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.103); catalogued as rs151126903, COSV64135502; called by muse, mutect2, varscan2
- EFL1 | c.2154A>G p.I718M | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as COSV51607400; called by muse, mutect2, varscan2
- EIF4G3 | c.4568A>G p.Q1523R | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51686921; called by muse, mutect2, varscan2
- EP400 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV57763435; called by muse, mutect2, varscan2
- EPHA1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144736263; called by muse, mutect2, varscan2
- EPPK1 | c.5356G>A p.V1786M | Missense Mutation (SNP) | VAF 15/462 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs368495019, COSV101599975; called by muse, mutect2
- ERBIN | c.338del p.N113Ifs*5 | Frame Shift Del (DEL) | VAF 57/210 reads (27%) | catalogued as rs1481998026; called by mutect2, pindel, varscan2
- ERG | c.821C>T p.T274M (on ENST00000398919 / NM_001243428.1; = p.T250M on NM_004449.4) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.083); catalogued as rs751217612, COSV55735173; called by muse, mutect2, varscan2
- ERICH1 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV50639183; called by muse, mutect2, varscan2
- ERLEC1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 83/468 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1463619232, COSV51752548; called by muse, mutect2
- ERN1 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs776930056, COSV70503182; called by muse, mutect2, varscan2
- ESRP1 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1320443775, COSV64411056; called by muse, mutect2, varscan2
- ETV3 | c.400+4A>C | Splice Region (SNP) | VAF 175/546 reads (32%) | catalogued as COSV58748230; called by muse, mutect2, varscan2
- FAAH2 | c.463del p.T155Qfs*9 | Frame Shift Del (DEL) | VAF 99/311 reads (32%) | catalogued as COSV100887419; called by mutect2, pindel, varscan2
- FAM120B | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 21/532 reads (4%) | catalogued as COSV53005961; called by muse, mutect2
- FAM126A | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 132/565 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV69017297; called by muse, mutect2, varscan2
- FAM13B | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 199/780 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV50368593; called by muse, mutect2, varscan2
- FAM186B | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV57722161; called by muse, mutect2, varscan2
- FAM53C | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs777338677, COSV53511210; called by muse, mutect2, varscan2
- FAT1 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs377259095; called by muse, mutect2, varscan2
- FBXL4 | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV57748014; called by muse, mutect2, varscan2
- FBXO16 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60776721; called by muse, mutect2, varscan2
- FGFRL1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs755567722, COSV53258276; called by muse, mutect2, varscan2
- FLNA | c.7568G>C p.S2523T (on ENST00000369850 / NM_001110556.2; = p.S2515T on NM_001456.3) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV61046749; called by muse, mutect2, varscan2
- FOXH1 | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56761905; called by muse, mutect2, varscan2
- FOXO1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV65427448; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 114/419 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs377042126, COSV63049672; called by muse, mutect2, varscan2
- FREM2 | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs368536400; called by muse, mutect2, varscan2
- FYCO1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV56117372; called by muse, mutect2
- GAL3ST4 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1226852342, COSV52785674; called by muse, mutect2
- GAN | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs112201678, CM002988, COSV73721073; called by muse, mutect2, varscan2
- GBF1 | c.3869C>T p.A1290V (on ENST00000369983 / NM_001377137.1; = p.A1289V on NM_004193.3) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV64145485; called by muse, mutect2, varscan2
- GLTP | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV59173207; called by muse, mutect2, varscan2
- GNPAT | c.844A>T p.I282F | Missense Mutation (SNP) | VAF 154/453 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64153771; called by muse, mutect2, varscan2
- GON4L | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.326); catalogued as rs202146983; called by muse, mutect2, varscan2
- GPR142 | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV59519786; called by muse, mutect2, varscan2
- GPR152 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs755398795, COSV56885183; called by muse, mutect2, varscan2
- GPR34 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs142652017, COSV59370464; called by muse, mutect2, varscan2
- GRAMD4 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs745727242, COSV63031147; called by muse, mutect2, varscan2
- GRHL1 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 109/403 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs568011556, COSV61409336; called by muse, mutect2, varscan2
- GRIK4 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs556909844, COSV70804162; called by muse, mutect2
- GRM2 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV56585816; called by muse, mutect2, varscan2
- GRM7 | c.2427dup p.G810Wfs*44 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | catalogued as rs747773579; called by mutect2, varscan2
- GSR | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 155/427 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.283); catalogued as rs144097786; called by muse, mutect2, varscan2
- GYPC | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99391740; called by muse, mutect2
- GZMA | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 15/360 reads (4%) | catalogued as COSV57113740; called by muse, mutect2
- H2AC12 | c.367_368del p.S123Pfs*3 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | catalogued as rs950440971; called by pindel, varscan2
- H2AP | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV61910988; called by muse, mutect2, varscan2
- H2BC5 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.099); catalogued as rs760339726, COSV56800309, COSV56802206; called by muse, mutect2, varscan2
- H4C9 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV62890043; called by muse, mutect2, varscan2
- HAVCR1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 174/565 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs762365419, COSV59401239; called by muse, mutect2
- HDGFL2 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs199605023, COSV56683730; called by muse, mutect2, varscan2
- HDX | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 272/873 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as COSV52979038; called by muse, mutect2, varscan2
- HEATR6 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 24/523 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51747066; called by muse, mutect2
- HERC1 | c.3541G>A p.G1181S | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324093486, COSV71248795; called by muse, mutect2, varscan2
- HGH1 | c.793C>A p.R265= | Splice Region (SNP) | VAF 76/337 reads (23%) | catalogued as COSV61690912; called by muse, mutect2, varscan2
- HINFP | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV63432283; called by muse, mutect2, varscan2
- HIVEP3 | c.1602del p.V535Cfs*4 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs1241831148; called by mutect2, pindel, varscan2
- HMBS | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs201909197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNF4A | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371827863; called by muse, mutect2, varscan2
- HOXA7 | c.246C>A p.C82* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs750200293, COSV54216980, COSV54218300; called by muse, mutect2, varscan2
- HTR2A | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV66327719; called by muse, mutect2
- HTR5A | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 144/411 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV55284786, COSV99839543; called by muse, mutect2, varscan2
- IFI44L | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60728333; called by muse, mutect2, varscan2
- IFNLR1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV59526963; called by muse, mutect2, varscan2
- IGLV3-27 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs751481735; called by mutect2, pindel, varscan2
- IGSF22 | c.2404C>T p.P802S (on ENST00000319338; = p.P903S on NM_173588.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV55010124, COSV55011190; called by muse, mutect2, varscan2
- IL9R | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54900733; called by muse, mutect2
- IMMP2L | c.303C>T p.V101= | Splice Region (SNP) | VAF 26/428 reads (6%) | catalogued as COSV59249861; called by muse, mutect2
- INO80C | c.19A>T p.I7F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV52034507; called by muse, mutect2, varscan2
- INPP5F | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs554637418, COSV62822305; called by muse, mutect2, varscan2
- IQGAP1 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51587760; called by muse, mutect2, varscan2
- IRF4 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66704986, COSV66705566; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 16/36 reads (44%) | catalogued as rs761880048; called by mutect2, varscan2
- ITPRIP | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53392197; called by muse, mutect2, varscan2
- ITSN1 | c.472del p.L158Wfs*37 | Frame Shift Del (DEL) | VAF 41/166 reads (25%) | catalogued as COSV66083080; called by mutect2, pindel, varscan2
- JAG1 | c.270del p.C92Afs*69 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as CD062180, CX062302; called by mutect2, pindel
- JAG2 | c.2986C>A p.R996S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59310758; called by muse, mutect2, varscan2
- KAT6A | c.5102C>T p.P1701L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs199692549, COSV55908290; called by muse, varscan2
- KCNAB3 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58140866; called by muse, mutect2, varscan2
- KCNC4 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as rs761948155, COSV63926046; called by muse, mutect2, varscan2
- KCNG1 | c.1427G>T p.R476M | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV65369620; called by muse, mutect2, varscan2
- KCNH6 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139452323; called by muse, mutect2, varscan2
- KCNH8 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60460404; called by muse, mutect2
- KCTD19 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs370173436, COSV58573652; called by muse, mutect2, varscan2
- KDM3B | c.4739G>T p.G1580V | Missense Mutation (SNP) | VAF 200/657 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV58692556; called by muse, mutect2, varscan2
- KDM5A | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66994082; called by muse, varscan2
- KIAA1217 | c.2932A>C p.N978H | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56819188; called by muse, varscan2
- KIAA1549L | c.3553G>A p.A1185T (on ENST00000321505; = p.A1482T on NM_012194.3) | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55776653; called by muse, mutect2, varscan2
- KIAA2013 | c.1106T>C p.M369T | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs772905077, COSV64860844; called by muse, mutect2, varscan2
- KIF5A | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54054227; called by muse, mutect2, varscan2
- KIRREL2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs571708243, COSV52874405; called by muse, mutect2, varscan2
- KLF11 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768653861, COSV59940912; called by muse, varscan2
- KLF3 | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV54711475; called by muse, mutect2, varscan2
- KLHL15 | c.74A>T p.Y25F | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV60141172; called by muse, mutect2, varscan2
- KLHL4 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 142/456 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV64140331, COSV64144510; called by muse, mutect2, varscan2
- KLHL4 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64144516; called by muse, mutect2, varscan2
- KLHL42 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760494357, COSV67146005; called by muse, mutect2, varscan2
- KMT2B | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as rs201585209; called by mutect2, varscan2
- KRT6C | c.516_518del p.N172del | In Frame Del (DEL) | VAF 53/274 reads (19%) | catalogued as rs267607474; called by pindel, varscan2
- KTN1 | c.1217T>A p.M406K | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as COSV68024260; called by muse, mutect2, varscan2
- LAG3 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs768238314, COSV52568168; called by muse, mutect2, varscan2
- LARP7 | c.246dup p.L83Ifs*4 | Frame Shift Ins (INS) | VAF 125/471 reads (27%) | catalogued as rs1318486735; called by mutect2, pindel, varscan2
- LDB2 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58774019; called by muse, mutect2
- LGALS3 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs974856973, COSV54305832; called by muse, mutect2, varscan2
- LHX9 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV61329835; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 156/560 reads (28%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMO7 | c.2597G>A p.R866H (on ENST00000357063; = p.R547H on NM_005358.5) | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753624038, COSV58541229; called by muse, mutect2, varscan2
- LNX2 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1470999230, COSV60336834; called by muse, mutect2, varscan2
- LOXL4 | c.2096T>C p.V699A | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53257736; called by muse, mutect2, varscan2
- LPA | c.5102T>C p.V1701A | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60304886; called by muse, mutect2, varscan2
- LRP1B | c.7483C>T p.R2495* | Nonsense Mutation (SNP) | VAF 266/597 reads (45%) | catalogued as COSV67184084; called by muse, mutect2, varscan2
- LRPPRC | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 96/619 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs776514302, COSV53240279; called by muse, mutect2, varscan2
- LRRC15 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs536324527, COSV61650684; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 52/250 reads (21%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC7 | c.2917del p.L973* (on ENST00000651989 / NM_001370785.2; = p.L940* on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/153 reads (22%) | catalogued as COSV50466223; called by mutect2, pindel, varscan2
- LSM14A | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.469); catalogued as rs147367720; called by muse, mutect2, varscan2
- MACROH2A2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1437666658, COSV64706954; called by muse, mutect2, varscan2
- MAGED2 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV54498625; called by muse, mutect2, varscan2
- MAN1C1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777179317, COSV56046451; called by muse, mutect2, varscan2
- MAP1LC3C | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV61803867; called by muse, mutect2, varscan2
- MAP2K3 | c.594C>G p.I198M (on ENST00000342679 / NM_145109.3; = p.I169M on NM_002756.4) | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV57571461; called by muse, mutect2, varscan2
- MAP7 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375395484; called by muse, varscan2
- MAPT | c.1321A>G p.K441E (on ENST00000262410 / NM_001377265.1; = p.K366E on NM_016835.4) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV52242722; called by muse, mutect2, varscan2
- MARCHF5 | c.688A>T p.S230C | Missense Mutation (SNP) | VAF 113/351 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV62770141; called by muse, mutect2, varscan2
- MED12 | c.1617G>T p.E539D | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV61345906; called by muse, mutect2, varscan2
- MED13 | c.4739A>G p.Q1580R | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.133); catalogued as COSV67264995; called by muse, mutect2, varscan2
- MEPE | c.570C>A p.H190Q | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.505); catalogued as COSV63073350; called by muse, mutect2, varscan2
- MIB1 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV55092292; called by muse, mutect2, varscan2
- MIDEAS | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs567181899, COSV54096327; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MLLT6 | c.828_830del p.S277del | In Frame Del (DEL) | VAF 54/209 reads (26%) | catalogued as rs755145223; called by pindel, varscan2
- MRPL10 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781472477, COSV50111164; called by muse, mutect2
- MSH5 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV65210319; called by muse, mutect2, varscan2
- MTNR1A | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs762288381, COSV56156348; called by muse, mutect2, varscan2
- MTOR | c.3198A>T p.E1066D | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV63874208; called by muse, mutect2, varscan2
- MYH1 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.169); catalogued as COSV56852012; called by muse, mutect2
- MYH2 | c.4076C>T p.S1359F | Missense Mutation (SNP) | VAF 109/425 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55442006; called by muse, mutect2, varscan2
- MYH6 | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 124/421 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV62447646; called by muse, mutect2, varscan2
- MYLK | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776636237, COSV60614521; ClinVar: uncertain significance; called by muse, mutect2
- NALCN | c.3578G>A p.R1193H | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs767265201, COSV51947471; called by muse, mutect2, varscan2
- NAPEPLD | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 153/508 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58523006; called by muse, mutect2, varscan2
- NBAS | c.6529G>A p.V2177I | Missense Mutation (SNP) | VAF 105/507 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV55728251; called by muse, mutect2, varscan2
- NBAS | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 194/537 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55728263; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 94/340 reads (28%) | catalogued as rs763376147; called by mutect2, varscan2
- NBEAL2 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs372051707; called by mutect2, varscan2
- NCAPD2 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.188); catalogued as rs780825688, COSV59700807; called by muse, mutect2, varscan2
- NELFB | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753890137, COSV58025653; called by muse, mutect2, varscan2
- NEMP1 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as rs752871216, COSV100272028, COSV55663581; called by muse, mutect2, varscan2
- NETO1 | c.414del p.F138Lfs*29 | Frame Shift Del (DEL) | VAF 65/243 reads (27%) | catalogued as rs1568270951, COSV55001882; called by mutect2, pindel, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 33/118 reads (28%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NKRF | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 139/454 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58662178; called by muse, mutect2, varscan2
- NLRP4 | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.451); catalogued as COSV56717323; called by muse, mutect2, varscan2
- NPC1L1 | c.808del p.Q270Rfs*84 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1444211657; called by mutect2, pindel
- NRROS | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV60746671; called by muse, mutect2, varscan2
- NTRK2 | c.2017G>A p.V673M (on ENST00000323115 / NM_001369534.1; = p.V689M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870391; called by muse, mutect2, varscan2
- OBSCN | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs780411914, COSV52793150; called by mutect2, varscan2
- OR1M1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV70037132; called by muse, mutect2, varscan2
- OR2D3 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58573355; called by muse, mutect2, varscan2
- OR2M3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 156/529 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs778299127, COSV71759161; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52H1 | c.793C>T p.R265C (on ENST00000322653; = p.R271C on NM_001005289.1) | Missense Mutation (SNP) | VAF 46/672 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs776491274, COSV59505819; called by muse, mutect2
- OR5AR1 | c.924del p.K308Nfs*8 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs1179572364; called by mutect2, pindel, varscan2
- OR6K2 | c.752T>G p.L251R | Missense Mutation (SNP) | VAF 115/312 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62743763; called by muse, mutect2, varscan2
- OTOF | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV55508766; called by muse, mutect2, varscan2
- OTUD7A | c.1439C>T p.S480L (on ENST00000307050 / NM_001382637.1; = p.S473L on NM_130901.3) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1489456306, COSV61040614; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- P3H4 | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV62680393; called by muse, mutect2, varscan2
- PBX3 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60731162; called by muse, mutect2, varscan2
- PCDHA4 | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793750, COSV63543369; called by muse, mutect2, varscan2
- PCDHA5 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1554128404, COSV65350329; called by muse, mutect2, varscan2
- PCDHB7 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs782364415, COSV50762092; called by muse, mutect2, varscan2
- PCNT | c.8023C>T p.R2675W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs771547665, COSV64030233; called by muse, mutect2, varscan2
- PDCD7 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV52600872; called by muse, mutect2, varscan2
- PGM2L1 | c.1070T>C p.L357S | Missense Mutation (SNP) | VAF 140/538 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV53347981; called by muse, mutect2, varscan2
- PIWIL2 | c.917T>A p.I306N | Missense Mutation (SNP) | VAF 122/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63252524; called by muse, mutect2, varscan2
- PKD2 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 167/600 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs977431912, COSV52936726; called by muse, mutect2, varscan2
- PLA2G6 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs781706286, COSV59271378; called by muse, mutect2, varscan2
- PLD5 | c.1012C>T p.Q338* (on ENST00000442594; = p.Q276* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/316 reads (9%) | catalogued as rs1363786539, COSV59154782, COSV59172508; called by muse, mutect2, varscan2
- PLEKHN1 | c.1643C>T p.P548L (on ENST00000379409; = p.P496L on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV58022597; called by muse, mutect2, varscan2
- PLXNA4 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773666064, COSV58108758; called by muse, mutect2, varscan2
- PODXL | c.1184G>A p.C395Y (on ENST00000378555 / NM_001018111.3; = p.C363Y on NM_005397.4) | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59871182; called by muse, mutect2, varscan2
- POMT1 | c.1261del p.L421* | Frame Shift Del (DEL) | VAF 90/286 reads (31%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- POTEF | c.358T>C p.W120R | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62542120; called by muse, mutect2, varscan2
- POU2F1 | c.1904C>T p.T635I (on ENST00000541643 / NM_001365848.1; = p.T658I on NM_002697.4) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54820344; called by muse, mutect2
- PPIC | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1357084862, COSV60574934; called by muse, mutect2
- PRADC1 | c.563G>T p.W188L | Missense Mutation (SNP) | VAF 140/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57820625; called by muse, mutect2, varscan2
- PRDM14 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52573470, COSV99399912; called by muse, mutect2, varscan2
- PSMA8 | c.150del p.K50Nfs*12 | Frame Shift Del (DEL) | VAF 154/489 reads (31%) | catalogued as rs749240094; called by mutect2, varscan2
- PSME4 | c.5413dup p.T1805Nfs*11 | Frame Shift Ins (INS) | VAF 241/607 reads (40%) | catalogued as rs1215842444; called by mutect2, varscan2
- PTCH1 | c.2703G>T p.Q901H | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV59482523; called by muse, mutect2, varscan2
- PTCH2 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs202184038, COSV63400187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGDS | c.573G>T p.*191Yext*14 | Nonstop Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV56400818; called by muse, mutect2, varscan2
- PTPRD | c.2151A>T p.K717N | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV61960485; called by muse, mutect2
- RAD51D | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV60005361; called by muse, mutect2, varscan2
- RALGAPA2 | c.5379del p.F1793Lfs*9 | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | catalogued as rs1266187100, COSV104390311; called by mutect2, pindel, varscan2
- RASGRF1 | c.2900A>G p.Q967R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV67250531; called by muse, mutect2, varscan2
- RBBP9 | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61500059; called by muse, mutect2, varscan2
- RBM12 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58290226; called by muse, mutect2, varscan2
- RBM33 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.154); catalogued as COSV56634427; called by muse, mutect2, varscan2
- RBMX | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.207); catalogued as COSV100284476, COSV57810129; called by muse, mutect2, varscan2
- RECK | c.1326del p.K442Nfs*27 | Frame Shift Del (DEL) | VAF 117/388 reads (30%) | catalogued as rs71508012; called by mutect2, pindel, varscan2
- RECK | c.1882T>C p.F628L | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65035747; called by muse, mutect2, varscan2
- RGS17 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 18/595 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52809282, COSV52811996; called by muse, mutect2
- RHCG | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51514950, COSV51516968; called by muse, mutect2, varscan2
- RNF19A | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 25/800 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV61993907; called by muse, mutect2
- RNF213 | c.14044G>A p.A4682T | Missense Mutation (SNP) | VAF 116/362 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs746242138, COSV60402165; called by muse, mutect2, varscan2
- RNF25 | c.749dup p.I251Nfs*3 | Frame Shift Ins (INS) | VAF 26/167 reads (16%) | catalogued as rs746813141; called by mutect2, varscan2
- RNF31 | c.2770G>A p.G924S | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1409264921, COSV60727430; called by muse, mutect2, varscan2
- ROBO1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1007241533, COSV71392121; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 76/204 reads (37%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP38 | c.80A>T p.N27I | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65382541; called by muse, mutect2, varscan2
- RPUSD3 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV59614976; called by muse, mutect2, varscan2
- RSRC1 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 135/453 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); catalogued as COSV55832823; called by muse, mutect2, varscan2
- RUFY1 | c.2074T>A p.C692S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60161635; called by mutect2, varscan2
- RUNX1T1 | c.1213G>C p.G405R (on ENST00000265814 / NM_001198628.1; = p.G378R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.439); catalogued as COSV56153354, COSV99755860; called by muse, mutect2, varscan2
- RUNX3 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV58244788, COSV58244851; called by muse, mutect2, varscan2
- SACS | c.10256G>A p.R3419H | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as rs536675517, COSV66535530; called by muse, mutect2, varscan2
- SAFB | c.2371G>A p.G791S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs776099156, COSV52652398; called by muse, varscan2
- SAMD9 | c.3784T>G p.F1262V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV66076470; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 130/437 reads (30%) | catalogued as COSV59083791; called by mutect2, varscan2
- SART3 | c.1120C>T p.R374* (on ENST00000228284; = p.R356* on NM_014706.4) | Nonsense Mutation (SNP) | VAF 14/429 reads (3%) | catalogued as COSV57205123, COSV99934455; called by muse, mutect2
- SBNO2 | c.128_130del p.F43del | In Frame Del (DEL) | VAF 37/155 reads (24%) | catalogued as rs770074633; called by mutect2, pindel, varscan2
- SCN10A | c.3971C>T p.S1324L | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs756046052, COSV71862048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16A | c.1689dup p.K564* | Frame Shift Ins (INS) | VAF 15/61 reads (25%) | catalogued as rs1187752611; called by mutect2, varscan2
- SEC31A | c.985A>G p.S329G | Missense Mutation (SNP) | VAF 110/383 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52347670; called by muse, mutect2, varscan2
- SEMA4F | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 162/309 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.442); catalogued as COSV60282006, COSV60284107; called by muse, mutect2, varscan2
- SFMBT2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.319); catalogued as rs778212893, COSV62806905, COSV62812334; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs1260834379; called by mutect2, varscan2
- SHB | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778794079, COSV66629617; called by muse, mutect2, varscan2
- SHISAL2A | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs752097440, COSV68979687; called by muse, mutect2, varscan2
- SLBP | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 182/501 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs751873933, COSV59184017; called by muse, mutect2, varscan2
- SLC16A14 | c.1481T>G p.I494S | Missense Mutation (SNP) | VAF 38/564 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54619551; called by muse, mutect2
- SLC22A11 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs1301814123, COSV57251724, COSV57254008; called by muse, mutect2, varscan2
- SLC22A25 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV60597158; called by muse, mutect2, varscan2
- SLC25A37 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV51564907; called by muse, mutect2, varscan2
- SLC35F3 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.993); catalogued as COSV64029169; called by muse, mutect2, varscan2
- SLC39A6 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV52369022; called by muse, mutect2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 97/171 reads (57%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A11 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs138917586; called by muse, mutect2, varscan2
- SLC52A1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as rs201477941; called by muse, mutect2, varscan2
- SLC7A1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.199); catalogued as rs773951324, COSV66331000; called by muse, mutect2, varscan2
- SLITRK3 | c.2555del p.G852Efs*34 | Frame Shift Del (DEL) | VAF 39/171 reads (23%) | catalogued as COSV53850888, COSV53852897; called by mutect2, pindel, varscan2
- SLITRK4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1158231525, COSV62024935; called by muse, mutect2, varscan2
- SMARCAL1 | c.2324A>G p.E775G | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV61921954; called by muse, mutect2, varscan2
- SMARCC2 | c.3583del p.L1195Cfs*88 | Frame Shift Del (DEL) | VAF 52/184 reads (28%) | catalogued as rs1224281535; called by mutect2, pindel, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 84/362 reads (23%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SNRNP200 | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60491738; called by muse, mutect2, varscan2
- SPATA46 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as rs370172196, COSV62633546; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs750890082; called by mutect2, varscan2
- SPEM1 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV57210887; called by muse, mutect2, varscan2
- SPEN | c.6029G>A p.R2010H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs530603850, COSV65364244; called by muse, mutect2, varscan2
- SPOP | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 133/327 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV61653170; called by muse, mutect2, varscan2
- SRD5A2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.177); catalogued as rs1186430097, CM101354, COSV51871152; called by muse, mutect2, varscan2
- SRRD | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV53226841, COSV53228149; called by muse, varscan2
- STAB2 | c.3199G>T p.G1067C | Missense Mutation (SNP) | VAF 125/383 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66342110; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 70/333 reads (21%) | catalogued as rs747003550; called by mutect2, varscan2
- SYMPK | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as rs781582819, COSV55611569; called by muse, mutect2, varscan2
- SYNJ1 | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59151414; called by muse, mutect2, varscan2
- SYTL5 | c.1770A>T p.E590D | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV52902890; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TAGAP | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs1163344179, COSV57851040; called by muse, mutect2, varscan2
- TBC1D10B | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.379); catalogued as rs896492298, COSV59769211; called by muse, mutect2, varscan2
- TBC1D22B | c.530dup p.M178Nfs*22 | Frame Shift Ins (INS) | VAF 29/127 reads (23%) | catalogued as rs757209781; called by mutect2, varscan2
- TCHH | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV64276010; called by muse, mutect2, varscan2
- TEKT2 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs926274967, COSV52881413; called by muse, mutect2, varscan2
- TENM2 | c.7848G>T p.K2616N (on ENST00000518659 / NM_001122679.2; = p.K2377N on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV69135085; called by muse, mutect2, varscan2
- TENT2 | c.1386G>A p.W462* | Nonsense Mutation (SNP) | VAF 85/285 reads (30%) | catalogued as COSV57138060; called by muse, mutect2, varscan2
- TES | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs750864842, COSV64042800; called by muse, mutect2, varscan2
- TEX12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 154/544 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV54784285, COSV54784465; called by muse, mutect2
- TFDP3 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1044980404, COSV59537683; called by muse, mutect2, varscan2
- TFIP11 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1163273261, COSV53226850; called by muse, mutect2, varscan2
- TGFBI | c.1511C>A p.T504N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV59352389; called by muse, mutect2, varscan2
- TGM1 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV52864111; called by muse, mutect2, varscan2
- TGM2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780860226, COSV63931865; called by muse, mutect2, varscan2
- THOC6 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 113/359 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs377615260, COSV50187861; called by muse, mutect2, varscan2
- TICRR | c.5183G>A p.S1728N | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.079); catalogued as COSV51543665; called by muse, mutect2, varscan2
- TIMELESS | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV57511437; called by muse, mutect2, varscan2
- TMEM117 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56910200; called by muse, mutect2, varscan2
- TMEM132E | c.1887C>G p.S629R (on ENST00000321639; = p.S719R on NM_001304438.2) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.173); catalogued as COSV58698475; called by muse, mutect2, varscan2
- TMEM181 | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 120/324 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.167); catalogued as COSV65564388; called by muse, mutect2, varscan2
- TMEM200C | c.62del p.P21Qfs*22 | Frame Shift Del (DEL) | VAF 20/171 reads (12%) | catalogued as rs756579008; called by mutect2, pindel
- TNFRSF11B | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 185/572 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs753578962, COSV52072098; called by muse, mutect2, varscan2
- TNNT1 | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.403); catalogued as rs1276254454, COSV52572400; called by muse, mutect2, varscan2
- TOGARAM1 | c.1918T>C p.Y640H | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV61888678; called by muse, mutect2, varscan2
- TPPP3 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52084299; called by muse, mutect2, varscan2
- TRAPPC11 | c.9del p.T4Hfs*19 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as COSV58219653; called by mutect2, pindel, varscan2
- TRARG1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as rs370410748, COSV61563388; called by muse, varscan2
- TRIM72 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs1185990761, COSV59068775, COSV59069984; called by muse, mutect2, varscan2
- TRIP12 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as CM124529, COSV52266220; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs760928888; called by mutect2, varscan2
- TSPAN31 | c.66G>A p.L22= | Splice Region (SNP) | VAF 112/392 reads (29%) | catalogued as COSV57276530; called by muse, mutect2, varscan2
- TSSC4 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV50161987; called by muse, mutect2
- TTC7A | c.2318C>T p.T773M | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757752980, COSV55412891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTF1 | c.821del p.K274Sfs*149 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs770528448; called by mutect2, varscan2
- TTN | c.83000A>G p.Y27667C (on ENST00000591111; = p.Y20243C on NM_003319.4) | Missense Mutation (SNP) | VAF 378/751 reads (50%) | PolyPhen probably damaging (0.999); catalogued as COSV60172265; called by muse, mutect2, varscan2
- TTN | c.26795C>T p.T8932M (on ENST00000591111; = p.T8005M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | PolyPhen benign (0.003); catalogued as rs745792278, COSV60026005, COSV60085709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.4118C>T p.A1373V (on ENST00000591111; = p.A1327V on NM_003319.4) | Missense Mutation (SNP) | VAF 62/240 reads (26%) | PolyPhen probably damaging (0.997); catalogued as rs139294675; called by muse, mutect2, varscan2
- TUB | c.671G>A p.S224N (on ENST00000299506 / NM_177972.3; = p.S279N on NM_003320.4) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55108862; called by muse, mutect2, varscan2
- TUBGCP2 | c.1688del p.T563Rfs*15 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV53306688; called by mutect2, pindel, varscan2
- TUBGCP6 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as rs542258273, COSV50557228; called by muse, mutect2, varscan2
- UBL4A | c.362G>T p.R121M | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54836714; called by muse, mutect2, varscan2
- UBL4A | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54836717; called by muse, mutect2, varscan2
- UGT1A1 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs770420506, COSV59392571; called by muse, mutect2
- UIMC1 | c.1744T>C p.C582R | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65894143; called by muse, mutect2, varscan2
- UNK | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53144048; called by muse, mutect2, varscan2
- UPF1 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53198443; called by muse, mutect2, varscan2
- USP25 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 126/493 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV53486588; called by muse, mutect2, varscan2
- USP3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV51428456; called by muse, mutect2, varscan2
- USP44 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51565314; called by muse, mutect2
- USP6NL | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1020447805, COSV53213167; called by muse, mutect2, varscan2
- VIL1 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV50291018; called by muse, mutect2, varscan2
- VPS18 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs376126131; called by muse, mutect2, varscan2
- VWA8 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs753556286, COSV55692220; called by muse, mutect2, varscan2
- VWC2L | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56973895; called by muse, mutect2
- WTAP | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61610380, COSV61610578; called by muse, mutect2, varscan2
- XPOT | c.2805+1G>A p.X935_splice | Splice Site (SNP) | VAF 16/406 reads (4%) | catalogued as COSV60346504; called by muse, mutect2
- YIF1A | c.391dup p.R131Pfs*8 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs761507279; called by mutect2, varscan2
- ZBTB17 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.165); catalogued as rs538764678, COSV65268658; called by muse, mutect2, varscan2
- ZCRB1 | c.116T>A p.V39D | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56891828; called by muse, mutect2, varscan2
- ZFHX4 | c.4304G>A p.R1435H | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757312872, COSV51463570; called by muse, mutect2, varscan2
- ZNF185 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59276959; called by muse, mutect2, varscan2
- ZNF189 | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs200682925, COSV52275892; called by muse, mutect2, varscan2
- ZNF211 | c.1630A>G p.K544E (on ENST00000347302 / NM_198855.4; = p.K557E on NM_006385.5) | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV53743511; called by muse, mutect2, varscan2
- ZNF283 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 206/797 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60288882; called by muse, mutect2, varscan2
- ZNF287 | c.1129T>A p.F377I | Missense Mutation (SNP) | VAF 105/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1001314230, COSV67688687; called by muse, mutect2, varscan2
- ZNF32 | c.26del p.L9Rfs*12 | Frame Shift Del (DEL) | VAF 72/239 reads (30%) | catalogued as COSV65641764; called by mutect2, pindel, varscan2
- ZNF394 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61794124; called by muse, mutect2, varscan2
- ZNF442 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 86/355 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV54422121; called by muse, mutect2, varscan2
- ZNF507 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 109/391 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555288271, COSV61332159; called by muse, mutect2, varscan2
- ZNF574 | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1568946736, COSV55905087; called by muse, mutect2, varscan2
- ZNF606 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58350770, COSV58350805; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF793 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 118/397 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs377400755; called by muse, mutect2, varscan2
- ABCB4 | c.2301del p.F767Lfs*30 | Frame Shift Del (DEL) | VAF 56/191 reads (29%) | called by mutect2, pindel, varscan2
- AC068580.4 | c.268del p.Q90Sfs*43 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- AFF2 | c.1887del p.K629Nfs*126 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | called by mutect2, pindel, varscan2
- APC | c.4778dup p.P1594Afs*38 | Frame Shift Ins (INS) | VAF 56/227 reads (25%) | called by mutect2, pindel, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.2893_2894del p.Q965Sfs*54 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | called by pindel, varscan2
- ARHGAP5 | c.926del p.L309* | Frame Shift Del (DEL) | VAF 50/161 reads (31%) | called by mutect2, pindel, varscan2
- ARHGEF18 | c.2111del p.P704Qfs*6 (on ENST00000359920 / NM_001130955.2; = p.P600Qfs*6 on NM_015318.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- ASTN2 | c.733dup p.S245Kfs*7 | Frame Shift Ins (INS) | VAF 14/64 reads (22%) | called by mutect2, pindel
- ATRN | c.693del p.F231Lfs*8 | Frame Shift Del (DEL) | VAF 233/704 reads (33%) | called by mutect2, varscan2
- AVEN | c.413del p.G138Efs*72 | Frame Shift Del (DEL) | VAF 157/525 reads (30%) | called by mutect2, pindel, varscan2
- CC2D2B | c.705dup p.D236* | Frame Shift Ins (INS) | VAF 12/114 reads (11%) | called by mutect2, pindel, varscan2
- CCR4 | c.1029del p.S344Afs*23 | Frame Shift Del (DEL) | VAF 50/221 reads (23%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- CEPT1 | c.553dup p.C185Lfs*28 | Frame Shift Ins (INS) | VAF 136/540 reads (25%) | called by mutect2, varscan2
- CFAP46 | c.7201del p.R2401Gfs*9 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, pindel, varscan2
- CIC | c.3347del p.P1116Qfs*45 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | called by mutect2, pindel, varscan2
- CNNM2 | c.1531del p.L511* | Frame Shift Del (DEL) | VAF 100/431 reads (23%) | called by mutect2, pindel, varscan2
- CNTN4 | c.1511del p.P504Lfs*18 | Frame Shift Del (DEL) | VAF 114/443 reads (26%) | called by mutect2, pindel, varscan2
- COL17A1 | c.2741del p.P914Qfs*152 | Frame Shift Del (DEL) | VAF 64/198 reads (32%) | called by mutect2, pindel, varscan2
- CR2 | c.2538del p.A847Pfs*3 | Frame Shift Del (DEL) | VAF 110/435 reads (25%) | called by mutect2, pindel, varscan2
- CSE1L | c.228+4_228+7del p.X76_splice | Splice Site (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- CTIF | c.245del p.P82Hfs*77 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- DAPP1 | c.218_219dup p.V74Lfs*2 | Frame Shift Ins (INS) | VAF 32/111 reads (29%) | called by mutect2, varscan2
- DDR1 | c.1448del p.P483Rfs*170 (on ENST00000324771; = p.P483Rfs*133 on NM_001954.4) | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- DENND2B | c.2273_2274del p.E758Vfs*2 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | called by pindel, varscan2
- DHDDS | c.517del p.V173Wfs*31 | Frame Shift Del (DEL) | VAF 126/455 reads (28%) | called by mutect2, pindel, varscan2
- DNAJC2 | c.845del p.K282Sfs*36 | Frame Shift Del (DEL) | VAF 251/955 reads (26%) | called by mutect2, pindel, varscan2
- DYRK2 | c.1361del p.N454Ifs*3 (on ENST00000344096 / NM_006482.3; = p.N381Ifs*3 on NM_003583.4) | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | called by mutect2, pindel, varscan2
- EFHC2 | c.1314del p.F438Lfs*4 | Frame Shift Del (DEL) | VAF 53/300 reads (18%) | called by pindel, varscan2
- ELF1 | c.1349_1350del p.T450Sfs*60 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, pindel, varscan2
- EMP2 | c.380del p.N127Tfs*7 | Frame Shift Del (DEL) | VAF 37/172 reads (22%) | called by mutect2, pindel, varscan2
- EPHX4 | c.515del p.G172Afs*2 | Frame Shift Del (DEL) | VAF 120/457 reads (26%) | called by mutect2, pindel, varscan2
- EPOR | c.444del p.V149Wfs*14 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, pindel
- EXOSC9 | c.611_612del p.Y204Ffs*7 | Frame Shift Del (DEL) | VAF 87/380 reads (23%) | called by pindel, varscan2
- FAM241B | c.145del p.R49Afs*24 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- FBN2 | c.2092_2093dup p.D699Lfs*26 | Frame Shift Ins (INS) | VAF 40/157 reads (25%) | called by mutect2, varscan2
- FHOD3 | c.2933dup p.P979Sfs*5 (on ENST00000359247 / NM_001281739.3; = p.P996Sfs*5 on NM_025135.5) | Frame Shift Ins (INS) | VAF 96/377 reads (25%) | called by mutect2, pindel, varscan2
- FMN2 | c.1270del p.R424Gfs*28 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- FMOD | c.169del p.V57Wfs*51 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- GNGT2 | c.22_24del p.K8del | In Frame Del (DEL) | VAF 88/338 reads (26%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.3380dup p.Q1128Tfs*15 | Frame Shift Ins (INS) | VAF 31/129 reads (24%) | called by mutect2, pindel, varscan2
- GRK3 | c.1152dup p.L385Sfs*11 | Frame Shift Ins (INS) | VAF 107/392 reads (27%) | called by mutect2, pindel, varscan2
- H3-5 | c.93del p.S32Lfs*5 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- HDAC5 | c.3286dup p.A1096Gfs*41 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- HSPA2 | c.413del p.G138Afs*8 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- HYKK | c.424del p.Q142Sfs*9 | Frame Shift Del (DEL) | VAF 41/136 reads (30%) | called by mutect2, pindel, varscan2
- IL6 | c.95del p.P32Qfs*8 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- JAKMIP1 | c.1326del p.F442Lfs*50 | Frame Shift Del (DEL) | VAF 78/314 reads (25%) | called by mutect2, pindel, varscan2
- KATNBL1 | c.30del p.K10Nfs*28 | Frame Shift Del (DEL) | VAF 86/306 reads (28%) | called by mutect2, pindel, varscan2
- KRTAP1-5 | c.365_368del p.D122Vfs*14 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- LAMB1 | c.927_928del p.C309* | Nonsense Mutation (DEL) | VAF 54/260 reads (21%) | called by pindel, varscan2
- LRFN2 | c.594del p.K198Nfs*29 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3702dup p.Q1235Tfs*4 | Frame Shift Ins (INS) | VAF 125/474 reads (26%) | called by mutect2, pindel, varscan2
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 82/268 reads (31%) | called by mutect2, varscan2
- MLLT6 | c.780del p.S261Afs*48 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- MLLT6 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MTERF2 | c.488del p.N163Mfs*8 | Frame Shift Del (DEL) | VAF 41/138 reads (30%) | called by mutect2, pindel, varscan2
- MZB1 | c.53del p.P18Qfs*65 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- NAGLU | c.606del p.R203Efs*36 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- NCAM2 | c.672_673del p.G225Rfs*27 | Frame Shift Del (DEL) | VAF 96/406 reads (24%) | called by pindel, varscan2
- NES | c.3745del p.V1249Cfs*11 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- NSD1 | c.4455del p.V1486* | Frame Shift Del (DEL) | VAF 58/235 reads (25%) | called by mutect2, pindel, varscan2
- NUP188 | c.2963del p.L988Cfs*26 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | called by mutect2, pindel, varscan2
- OR52A5 | c.33dup p.S12Lfs*43 | Frame Shift Ins (INS) | VAF 38/130 reads (29%) | called by mutect2, pindel, varscan2
- PLG | c.1586del p.N529Ifs*10 | Frame Shift Del (DEL) | VAF 79/300 reads (26%) | called by mutect2, pindel, varscan2
- PNPLA1 | c.488del p.P163Rfs*6 (on ENST00000394571 / NM_001374623.1; = p.P68Rfs*6 on NM_173676.2) | Frame Shift Del (DEL) | VAF 15/177 reads (8%) | called by mutect2, pindel
- POTEE | c.358T>C p.W120R | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- PRKDC | c.10814del p.N3605Tfs*48 | Frame Shift Del (DEL) | VAF 97/360 reads (27%) | called by mutect2, varscan2
- PRR15L | c.142_160del p.N48Afs*29 | Frame Shift Del (DEL) | VAF 100/414 reads (24%) | called by pindel, varscan2
- PTGES3L-AARSD1 | c.599_600del p.V200Afs*11 (on ENST00000421990 / NM_001136042.2; = p.V182Afs*11 on NM_025267.3) | Frame Shift Del (DEL) | VAF 31/129 reads (24%) | called by pindel, varscan2
- PTPN20 | c.560del p.N187Ifs*30 (on ENST00000374339 / NM_001042357.4; = p.N187Ifs*51 on NM_015605.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 209/654 reads (32%) | called by mutect2, varscan2
- RASGRF1 | c.1673dup p.P559Afs*20 | Frame Shift Ins (INS) | VAF 74/287 reads (26%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.1041del p.S348Afs*105 | Frame Shift Del (DEL) | VAF 79/322 reads (25%) | called by mutect2, pindel, varscan2
- SCML4 | c.842del p.G281Vfs*25 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- SCRIB | c.167dup p.R57Pfs*40 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- SESN3 | c.369_372del p.Y123* | Frame Shift Del (DEL) | VAF 70/222 reads (32%) | called by pindel, varscan2
- SHF | c.228_229del p.K77Efs*36 | Frame Shift Del (DEL) | VAF 57/198 reads (29%) | called by mutect2, pindel, varscan2
- SLF2 | c.1377_1378del p.N459Kfs*4 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | called by mutect2, pindel, varscan2
- SLFN5 | c.2216dup p.G740Wfs*8 | Frame Shift Ins (INS) | VAF 71/301 reads (24%) | called by mutect2, pindel, varscan2
- SLX4IP | c.644dup p.S216Ifs*15 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 25/182 reads (14%) | called by mutect2, varscan2
- TBC1D12 | c.2250del p.K750Nfs*9 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- TECTA | c.1987del p.E663Sfs*78 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- TENM3 | c.365del p.N122Mfs*4 | Frame Shift Del (DEL) | VAF 50/205 reads (24%) | called by mutect2, pindel, varscan2
- TGM6 | c.1078del p.Q360Rfs*99 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- TIAM2 | c.452del p.P151Hfs*23 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- TMIGD1 | c.473del p.N158Tfs*7 | Frame Shift Del (DEL) | VAF 65/258 reads (25%) | called by mutect2, pindel, varscan2
- TNRC6B | c.1124del p.N375Mfs*7 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- TOR1AIP1 | c.1188dup p.H397Tfs*3 | Frame Shift Ins (INS) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- UGT1A1 | c.353del p.K118Rfs*32 | Frame Shift Del (DEL) | VAF 115/294 reads (39%) | called by mutect2, pindel, varscan2
- USP15 | c.2520_2521del p.Y840* (on ENST00000280377 / NM_001351159.2; = p.Y811* on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 88/367 reads (24%) | called by mutect2, pindel, varscan2
- USP42 | c.1225del p.Y409Ifs*7 | Frame Shift Del (DEL) | VAF 136/516 reads (26%) | called by mutect2, pindel, varscan2
- USP50 | c.708dup p.Q237Sfs*17 (on ENST00000616326; = p.Q228Sfs*17 on NM_203494.5) | Frame Shift Ins (INS) | VAF 92/334 reads (28%) | called by mutect2, varscan2
- VAV3 | c.1635dup p.K546* | Frame Shift Ins (INS) | VAF 105/405 reads (26%) | called by mutect2, pindel, varscan2
- ZMYND12 | c.686del p.K229Sfs*20 | Frame Shift Del (DEL) | VAF 119/412 reads (29%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.2698del p.R900Efs*2 | Frame Shift Del (DEL) | VAF 63/218 reads (29%) | called by mutect2, pindel, varscan2
- ZSCAN26 | c.760_761del p.T254Gfs*8 (on ENST00000623276 / NM_001111039.2; = p.T120Gfs*8 on NM_152736.5) | Frame Shift Del (DEL) | VAF 46/180 reads (26%) | called by pindel, varscan2
- ABCB1 | c.525T>C p.L175= | Silent (SNP) | VAF 120/354 reads (34%) | catalogued as COSV55955667; called by muse, mutect2, varscan2
- ACACB | c.2103G>A p.G701= | Silent (SNP) | VAF 55/189 reads (29%) | catalogued as COSV58139087; called by muse, mutect2, varscan2
- ADAMTS2 | c.2217C>T p.I739= | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as COSV52381998; called by muse, mutect2, varscan2
- ADGRL3 | c.2982C>G p.L994= (on ENST00000506720 / NM_001322402.2; = p.L926= on NM_015236.6) | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV72231127; called by muse, mutect2, varscan2
- ADPRS | c.411G>A p.E137= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV52881419; called by muse, mutect2
- AFF2 | c.3639A>G p.P1213= | Silent (SNP) | VAF 105/309 reads (34%) | catalogued as COSV53996564; called by muse, mutect2, varscan2
- AKAP6 | c.942A>G p.A314= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV55220646; called by muse, mutect2, varscan2
- ALDH8A1 | c.690C>T p.T230= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs138741870; called by muse, mutect2, varscan2
- APBB1IP | c.1992C>T p.N664= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV66133844; called by muse, mutect2, varscan2
- ARID1B | c.6064C>T p.L2022= | Silent (SNP) | VAF 83/222 reads (37%) | catalogued as COSV51669157; called by muse, mutect2, varscan2
- ARID3C | c.405C>T p.N135= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV52407977; called by muse, mutect2
- B3GALNT2 | c.204C>T p.N68= | Silent (SNP) | VAF 102/334 reads (31%) | catalogued as rs1057182171, COSV58355975; called by muse, mutect2, varscan2
- BAZ2A | c.4287G>A p.Q1429= | Silent (SNP) | VAF 69/204 reads (34%) | catalogued as COSV51639481; called by muse, mutect2, varscan2
- BICC1 | c.915C>T p.S305= | Silent (SNP) | VAF 95/358 reads (27%) | catalogued as COSV54064922; called by muse, mutect2, varscan2
- BNC2 | c.3210C>T p.C1070= | Silent (SNP) | VAF 13/271 reads (5%) | catalogued as COSV66162194, COSV66169355; called by muse, mutect2
- BRD9 | c.1323C>T p.D441= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as rs1406821967, COSV60245226; called by muse, mutect2, varscan2
- BSG | c.789C>T p.D263= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV61077614; called by muse, mutect2, varscan2
- C1QTNF2 | c.453C>T p.G151= (on ENST00000393975; = p.G106= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV67432951, COSV67433381; called by muse, mutect2, varscan2
- CACNA1G | c.5031G>A p.Q1677= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV61731571; called by muse, mutect2, varscan2
- CAD | c.5754G>A p.L1918= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as COSV53028821; called by muse, mutect2, varscan2
- CAPN11 | c.1287T>C p.D429= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1179705200, COSV67238301; called by muse, mutect2, varscan2
- CARD11 | c.657C>T p.V219= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV62718407; called by muse, mutect2
- CARNS1 | c.2376C>T p.A792= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs368627620; called by muse, mutect2, varscan2
- CCDC125 | c.729C>T p.L243= | Silent (SNP) | VAF 123/412 reads (30%) | catalogued as COSV67288388; called by muse, mutect2, varscan2
- CCDC144A | c.96G>A p.Q32= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV61403919; called by muse, mutect2, varscan2
- CCDC51 | c.442T>C p.L148= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV56491682; called by muse, mutect2, varscan2
- CEL | c.186C>T p.T62= (on ENST00000673714; = p.T59= on NM_001807.6) | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as COSV60828356; called by muse, mutect2, varscan2
- CELSR1 | c.5433C>T p.G1811= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1209269252, COSV53093976; called by muse, mutect2, varscan2
- CHFR | c.969G>A p.T323= (on ENST00000432561 / NM_001161345.1; = p.T282= on NM_018223.2) | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs142975525; called by muse, mutect2, varscan2
- CYP17A1 | c.312C>T p.I104= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs777937209, COSV64004885; called by muse, mutect2, varscan2
- D2HGDH | c.933G>A p.E311= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as COSV58321833; called by muse, mutect2, varscan2
- DCAF4 | c.48C>T p.S16= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV62319975; called by muse, mutect2, varscan2
- DISP3 | c.3423G>A p.L1141= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as COSV53831203; called by muse, mutect2, varscan2
- DIXDC1 | c.1491G>A p.T497= (on ENST00000440460 / NM_001037954.4; = p.T286= on NM_033425.4) | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as rs377409061; called by muse, mutect2, varscan2
- DOCK2 | c.5154G>T p.S1718= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as COSV56964477; called by muse, mutect2, varscan2
- DOCK9 | c.4176A>G p.E1392= (on ENST00000376460 / NM_001366676.2; = p.E1393= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/295 reads (26%) | catalogued as COSV59635012; called by muse, mutect2, varscan2
- DVL3 | c.1461C>T p.S487= | Silent (SNP) | VAF 57/170 reads (34%) | catalogued as rs756254669, COSV57456878; called by muse, mutect2, varscan2
- EPHA7 | c.1368G>A p.Q456= | Silent (SNP) | VAF 16/432 reads (4%) | catalogued as COSV65186658; called by muse, mutect2
- EPS15 | c.1314G>A p.S438= | Silent (SNP) | VAF 168/457 reads (37%) | catalogued as rs145467749; called by muse, mutect2, varscan2
- ERMAP | c.1092T>C p.Y364= | Silent (SNP) | VAF 24/500 reads (5%) | catalogued as rs1319051877, COSV60274900; called by muse, mutect2
- ETV3L | c.165C>T p.R55= | Silent (SNP) | VAF 59/170 reads (35%) | catalogued as COSV71901149; called by muse, mutect2, varscan2
- FAM110A | c.211C>T p.L71= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55727513; called by muse, mutect2, varscan2
- FAM111B | c.1317A>G p.G439= | Silent (SNP) | VAF 54/158 reads (34%) | catalogued as rs773774347, COSV59112534; called by muse, mutect2, varscan2
- FAM20C | c.657C>T p.A219= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs375009760; called by muse, mutect2, varscan2
- FOXP2 | c.549G>A p.Q183= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1415137088, COSV63485681; called by muse, varscan2
- FSTL5 | c.225C>T p.H75= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV60207532; called by muse, mutect2, varscan2
- GALNT16 | c.1170C>T p.I390= | Silent (SNP) | VAF 62/182 reads (34%) | catalogued as rs1466489648, COSV61886700; called by muse, mutect2, varscan2
- GARNL3 | c.2304C>T p.T768= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs767319667, COSV100149918, COSV59228052; called by muse, mutect2, varscan2
- GGT6 | c.996G>A p.A332= (on ENST00000574154 / NM_001122890.3; = p.A300= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs147345619; called by muse, mutect2, varscan2
- GPR158 | c.681G>A p.R227= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs765588988, COSV66274964; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1275C>T p.G425= | Silent (SNP) | VAF 80/346 reads (23%) | called by muse, mutect2, varscan2
- GUCY2C | c.2796T>C p.V932= | Silent (SNP) | VAF 41/252 reads (16%) | catalogued as rs1415722316, COSV53792194; called by muse, mutect2, varscan2
- HSPA1L | c.1380G>A p.R460= | Silent (SNP) | VAF 66/192 reads (34%) | catalogued as COSV65149233, COSV65149399; called by muse, mutect2, varscan2
- HSPA9 | c.1848C>A p.S616= | Silent (SNP) | VAF 89/299 reads (30%) | catalogued as COSV51865199; called by muse, mutect2, varscan2
- IFI30 | c.462C>T p.D154= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV69576687; called by muse, mutect2, varscan2
- IL10RA | c.982C>T p.L328= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV57141300; called by muse, mutect2, varscan2
- IL17RD | c.1413G>A p.A471= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs747651301, COSV56338744; called by muse, mutect2, varscan2
- INPP4B | c.1056C>T p.H352= | Silent (SNP) | VAF 150/421 reads (36%) | catalogued as COSV53732803; called by muse, mutect2, varscan2
- INTS1 | c.3174T>G p.T1058= | Silent (SNP) | VAF 57/167 reads (34%) | catalogued as COSV67178270; called by muse, mutect2, varscan2
- IPO13 | c.825C>T p.Y275= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as rs1216097064, COSV64894689; called by muse, mutect2, varscan2
- IQCN | c.180G>A p.K60= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as COSV66575457; called by muse, mutect2, varscan2
- ITGA5 | c.579C>T p.R193= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV53219126; called by muse, mutect2, varscan2
- ITPR1 | c.6543C>T p.D2181= (on ENST00000354582; = p.D2126= on NM_002222.7) | Silent (SNP) | VAF 104/368 reads (28%) | catalogued as rs578051224, COSV56990162; called by muse, mutect2, varscan2
- KAT6A | c.5226C>T p.G1742= | Silent (SNP) | VAF 136/415 reads (33%) | catalogued as rs752976045, COSV55908279; called by muse, varscan2
- KCNA1 | c.99C>T p.H33= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV66837975; called by muse, mutect2
- KCTD14 | c.567G>A p.L189= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as COSV62001671; called by muse, mutect2, varscan2
- KIAA1217 | c.3046A>C p.R1016= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV56819196; called by muse, varscan2
- KIAA1217 | c.3888C>A p.T1296= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV56817465, COSV56819205; called by muse, mutect2, varscan2
- KIAA2026 | c.4485G>A p.A1495= | Silent (SNP) | VAF 72/271 reads (27%) | catalogued as rs754632331, COSV67353516; called by muse, mutect2, varscan2
- KIF20B | c.282T>G p.P94= | Silent (SNP) | VAF 108/339 reads (32%) | catalogued as COSV53310482; called by muse, mutect2, varscan2
- KIF7 | c.1740G>A p.P580= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs200473560, COSV67998419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL2 | c.246T>C p.H82= | Silent (SNP) | VAF 105/461 reads (23%) | catalogued as COSV56979380; called by muse, varscan2
- KRTAP3-1 | c.21C>T p.R7= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as COSV66957575; called by muse, mutect2, varscan2
- LIPC | c.585C>T p.A195= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as rs149322349; called by muse, mutect2, varscan2
- MAMLD1 | c.1815G>A p.Q605= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs1557406544, COSV53377592; called by muse, mutect2, varscan2
- MAP2K5 | c.876C>T p.N292= | Silent (SNP) | VAF 174/702 reads (25%) | catalogued as COSV51618395; called by muse, mutect2, varscan2
- MEST | c.387G>A p.A129= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as rs782327598, COSV56229007; called by muse, mutect2, varscan2
- MME | c.381T>A p.T127= | Silent (SNP) | VAF 99/359 reads (28%) | catalogued as COSV64708664; called by muse, mutect2, varscan2
- MTMR7 | c.1920T>C p.H640= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs761167196, COSV51668021; called by muse, mutect2, varscan2
- MUC16 | c.14190C>T p.D4730= | Silent (SNP) | VAF 81/195 reads (42%) | catalogued as rs1033836299, COSV67477704, COSV67504487; called by muse, mutect2, varscan2
- MYBPH | c.1182C>T p.T394= | Silent (SNP) | VAF 9/266 reads (3%) | catalogued as rs1387093081, COSV55143129; called by muse, mutect2
- MYO18A | c.3366C>T p.R1122= | Silent (SNP) | VAF 62/172 reads (36%) | catalogued as COSV62863063; called by muse, mutect2, varscan2
- NAGLU | c.1842C>T p.S614= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV56795421; called by muse, mutect2, varscan2
- NDRG2 | c.204C>T p.Y68= (on ENST00000298687 / NM_001354570.1; = p.Y54= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 119/435 reads (27%) | catalogued as COSV53873075; called by muse, mutect2, varscan2
- NRP2 | c.243C>T p.H81= | Silent (SNP) | VAF 121/281 reads (43%) | catalogued as rs757076695, COSV55923807; called by muse, mutect2, varscan2
- OR4A47 | c.321G>A p.G107= | Silent (SNP) | VAF 73/288 reads (25%) | catalogued as COSV71445048; called by muse, mutect2, varscan2
- OTUD6A | c.681C>T p.H227= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV57972605; called by muse, mutect2, varscan2
- PCDHA11 | c.1668C>T p.D556= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs370490786; called by muse, mutect2, varscan2
- PCDHB15 | c.2253C>T p.Y751= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as rs376420795; called by muse, mutect2, varscan2
- PCDHGA3 | c.1965C>T p.S655= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs758844138, COSV53980332; called by mutect2, varscan2
- PCF11 | c.2868T>C p.F956= | Silent (SNP) | VAF 10/324 reads (3%) | catalogued as COSV53534188; called by muse, mutect2
- PCSK1 | c.126C>T p.G42= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs1178235853, COSV60736311; called by muse, mutect2, varscan2
- PDZD2 | c.3927G>A p.S1309= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs377229414; called by muse, mutect2, varscan2
- PHOX2B | c.498G>A p.A166= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- PHRF1 | c.1581C>T p.R527= (on ENST00000264555 / NM_001286581.2; = p.R526= on NM_020901.4) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1323173408, COSV52758447; called by muse, mutect2, varscan2
- PICK1 | c.567C>T p.D189= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs150100384; called by muse, mutect2, varscan2
- PITX3 | c.732C>G p.A244= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV64174675; called by muse, varscan2
- POLDIP3 | c.966G>A p.V322= | Silent (SNP) | VAF 100/368 reads (27%) | catalogued as COSV52809557; called by muse, mutect2, varscan2
- PRR22 | c.654C>T p.L218= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs374535289, COSV100288468, COSV57832531; called by muse, mutect2, varscan2
- PSPC1 | c.1254T>C p.P418= | Silent (SNP) | VAF 74/484 reads (15%) | catalogued as COSV58889146; called by muse, varscan2
- PTBP1 | c.369C>T p.G123= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV62460836; called by muse, mutect2, varscan2
- PTGER2 | c.729C>T p.G243= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV55419372; called by muse, mutect2, varscan2
- PTPRM | c.2787C>T p.Y929= | Silent (SNP) | VAF 141/505 reads (28%) | catalogued as rs368053392; called by muse, mutect2, varscan2
- PTPRN2 | c.1938G>A p.R646= | Silent (SNP) | VAF 41/182 reads (23%) | catalogued as COSV67047706; called by muse, mutect2, varscan2
- RAPGEF1 | c.93A>G p.S31= | Silent (SNP) | VAF 246/875 reads (28%) | catalogued as rs768589172, COSV64700594; called by muse, mutect2, varscan2
- RBFOX1 | c.45C>T p.A15= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV60966309; called by muse, mutect2, varscan2
- RBM24 | c.501C>T p.A167= (on ENST00000379052 / NM_001143942.2; = p.A122= on NM_153020.2) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs768843893, COSV59002543; called by muse, varscan2
- RIPK3 | c.324C>T p.S108= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV53476245; called by muse, mutect2, varscan2
- RORA | c.501G>A p.Q167= (on ENST00000335670 / NM_134261.3; = p.Q192= on NM_002943.3) | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as COSV55041526; called by muse, mutect2, varscan2
- SDK1 | c.1386T>C p.N462= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs755551084, COSV67377495; called by muse, mutect2, varscan2
- SDK1 | c.2253G>A p.R751= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV67377500; called by muse, mutect2, varscan2
- SEMA4F | c.1279C>T p.L427= | Silent (SNP) | VAF 44/185 reads (24%) | catalogued as COSV60284114; called by muse, mutect2, varscan2
- SERPINA6 | c.231G>A p.L77= | Silent (SNP) | VAF 61/205 reads (30%) | catalogued as rs761397086, COSV58586062; called by muse, mutect2, varscan2
- SETBP1 | c.3081C>T p.D1027= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV56328296; called by muse, mutect2, varscan2
- SFN | c.294C>G p.T98= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV59433685; called by muse, mutect2, varscan2
- SH3BP4 | c.2361C>T p.C787= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100749181, COSV60644720; called by muse, mutect2, varscan2
- SHC2 | c.702C>T p.S234= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs1405433408, COSV52747578; called by muse, varscan2
- SLC12A2 | c.3048G>A p.Q1016= | Silent (SNP) | VAF 22/592 reads (4%) | catalogued as COSV52473359; called by muse, mutect2
- SLC26A9 | c.513C>T p.H171= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs915153205, COSV61604075; called by muse, mutect2, varscan2
- SLC2A8 | c.564C>T p.G188= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV64894773; called by muse, mutect2, varscan2
- SLC34A1 | c.1683G>A p.L561= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs932944352, COSV53692011; called by muse, mutect2, varscan2
- SLC6A19 | c.1887C>T p.N629= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs369149152; called by muse, mutect2, varscan2
- SLC8B1 | c.1581G>T p.V527= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs957837466, COSV52529129; called by muse, mutect2, varscan2
- SP3 | c.372T>C p.G124= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as COSV59469179; called by muse, mutect2, varscan2
- SPAM1 | c.804G>A p.Q268= | Silent (SNP) | VAF 35/299 reads (12%) | catalogued as COSV56145430; called by muse, mutect2, varscan2
- SPATA13 | c.1458C>T p.C486= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as rs946597717, COSV57978938; called by muse, mutect2, varscan2
- SPATA32 | c.150G>T p.V50= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV59304227; called by muse, mutect2, varscan2
- SPTAN1 | c.258A>G p.Q86= | Silent (SNP) | VAF 52/196 reads (27%) | catalogued as COSV63988270; called by muse, mutect2, varscan2
- SSX3 | c.198C>A p.I66= | Silent (SNP) | VAF 264/801 reads (33%) | catalogued as COSV53644893; called by muse, mutect2, varscan2
- STK36 | c.2490T>C p.H830= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV55328127; called by muse, mutect2, varscan2
- TANK | c.1074G>A p.P358= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs756973756, COSV52046100; called by muse, mutect2, varscan2
- TIMD4 | c.1006C>T p.L336= | Silent (SNP) | VAF 93/358 reads (26%) | catalogued as COSV50856835; called by muse, mutect2, varscan2
- TLE1 | c.1899G>T p.T633= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as rs774599116, COSV64719291, COSV64719443; called by muse, mutect2, varscan2
- TLE2 | c.1425C>T p.G475= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs371398220; called by muse, mutect2, varscan2
- TMEM101 | c.597C>T p.Y199= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs776905114, COSV52813540; called by muse, mutect2, varscan2
- TMEM259 | c.348G>A p.R116= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52261491; called by muse, mutect2, varscan2
- TRPM4 | c.3162C>T p.S1054= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs775430500, COSV53265403; called by muse, mutect2, varscan2
- TSC22D1 | c.1503G>A p.Q501= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs767989400, COSV71775449; called by muse, mutect2, varscan2
- TUBA3E | c.1317C>T p.S439= | Silent (SNP) | VAF 40/558 reads (7%) | catalogued as rs144996545; called by muse, mutect2
- TXNDC11 | c.654C>T p.Y218= | Silent (SNP) | VAF 12/388 reads (3%) | catalogued as rs1215657177, COSV51600829; called by muse, mutect2
- TXNDC5 | c.516A>G p.P172= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV65730674; called by muse, mutect2, varscan2
- TYK2 | c.864G>A p.G288= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV53388970; called by muse, mutect2, varscan2
- UCKL1 | c.1143G>A p.G381= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1443659253, COSV62403216; called by muse, mutect2, varscan2
- UGT2B15 | c.166T>C p.L56= | Silent (SNP) | VAF 90/316 reads (28%) | catalogued as COSV57735393; called by muse, mutect2, varscan2
- UNC13D | c.801T>C p.T267= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV52885795; called by muse, mutect2, varscan2
- VCAN | c.3381G>A p.G1127= | Silent (SNP) | VAF 5/136 reads (4%) | catalogued as COSV54109838; called by muse, mutect2
- VPS25 | c.78G>A p.R26= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV53821321; called by muse, mutect2, varscan2
- WNT2B | c.165C>T p.R55= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56675433; called by muse, mutect2, varscan2
- XDH | c.679C>T p.L227= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as COSV65149836; called by muse, mutect2, varscan2
- ZBBX | c.1710T>C p.T570= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as rs533119403, COSV56794130; called by muse, mutect2, varscan2
- ZBTB17 | c.1260C>T p.C420= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs950763626, COSV65270614; called by muse, mutect2
- ZC3H18 | c.2070C>T p.G690= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV56323137; called by muse, mutect2, varscan2
- ZMYM4 | c.834T>C p.N278= | Silent (SNP) | VAF 96/309 reads (31%) | catalogued as COSV58913344; called by muse, mutect2, varscan2
- ZNF331 | c.1332C>T p.C444= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs1435408843, COSV53476435; called by muse, mutect2, varscan2
- ZNF449 | c.1368G>A p.T456= | Silent (SNP) | VAF 23/297 reads (8%) | catalogued as rs138335708, COSV59347442; called by muse, mutect2
- ZNF594 | c.2100A>G p.R700= | Silent (SNP) | VAF 60/268 reads (22%) | catalogued as COSV68385755; called by muse, mutect2, varscan2
- ZNF623 | c.117G>A p.T39= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs201671001, COSV71697120; called by muse, mutect2, varscan2
- ZNF646 | c.4464G>A p.E1488= | Silent (SNP) | VAF 44/223 reads (20%) | catalogued as rs772825674, COSV54925375; called by muse, mutect2, varscan2
- ZNF689 | c.1494C>T p.N498= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs775225146, COSV54908336; called by muse, mutect2, varscan2
- ZNF70 | c.180T>C p.N60= | Silent (SNP) | VAF 72/220 reads (33%) | catalogued as rs779270037, COSV59533279; called by muse, mutect2, varscan2
- ZNF808 | c.597G>A p.R199= | Silent (SNP) | VAF 242/645 reads (38%) | catalogued as COSV63120519; called by muse, mutect2, varscan2
- ZYX | c.315C>A p.P105= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV59556873; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1194G>A | Intron (SNP) | VAF 24/86 reads (28%) | catalogued as rs761808179, COSV56099002; called by muse, mutect2, varscan2
- C11orf49 | chr11:47164253 G>T | 3'Flank (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99561978; called by muse, mutect2, varscan2
- GCNT2 | c.925+27347del | Intron (DEL) | VAF 43/154 reads (28%) | called by mutect2, pindel, varscan2
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 38/135 reads (28%) | catalogued as rs764079139; called by mutect2, pindel, varscan2
- PCDHA5 | c.2352+77del | Intron (DEL) | VAF 19/63 reads (30%) | catalogued as rs781996539; called by mutect2, pindel, varscan2
- TAOK2 | chr16:29990900 G>A | 3'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as COSV54230894; called by muse, mutect2, varscan2
